Gene-level copy-number profile of tumor specimen TCGA-PK-A5HC-01A from TCGA case TCGA-PK-A5HC, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 44.3 years (16,182 days).
Specimen TCGA-PK-A5HC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.c00b53a9-bb48-4841-974d-7087eacd5420.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PK-A5HC-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57d71f47-667f-4ba0-8078-07a909c95041

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 89; copy number 2: 3,514; copy number 3: 35; copy number 4: 27,593; copy number 5: 2,188; copy number 6: 17,761; copy number 7: 568; copy number 8: 4,399; copy number 9: 2,693; copy number 10: 37; copy number 11: 934.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PK-A5HC-01A-11D-A309-01): tumor purity 0.59, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr4:181,590,255–181,700,142, 2 genes: AC093840.2, AC084741.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,664 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–75,565,871, 378 genes, copy number 9 (broad region; genes not listed).
- chr6:41,335,608–42,500,022, 37 genes, copy number 10: NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1.
- chr6:47,231,532–58,438,364, 174 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr7:48,660,125–48,927,454, 6 genes, copy number 9: AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C.
- chr7:86,216,785–95,615,132, 142 genes, copy number 9 (broad region; genes not listed).
- chr9:5,084,999–5,437,925, 21 genes, copy number 9 (within-gene range 6–9): PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1.
- chr12:66,767–76,620,043, 1,878 genes, copy number 9–11 (broad region; genes not listed).
- chr16:5,033,923–35,912,516, 1,028 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
